MMRF case MMRF_2291 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/74736b86-8106-4c0e-a8d5-2b63090754cc

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.5 years (27,576 days); ISS stage: I; Days to last known disease status: 72 days; Days to last follow up: 72 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -104 (ECOG 0): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 80.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.922 mg/dL; Immunoglobulin G 22.7 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 4.9 mmol/L.
- Day -20 (ECOG 0): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 109 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 23.4 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.8 g/dL; Glucose 5.34 mmol/L.
- Day 72 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.55 mg/dL; Immunoglobulin G 8.69 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 6.22 mmol/L.

Other clinical attributes
- Day -104: Weight: 92 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Bladder Cancer.

Biospecimens (2 samples)
- Sample MMRF_2291_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -104 days.
- Sample MMRF_2291_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -104 days.
